Somatic mutation profile of tumor specimen TCGA-DD-AACS-01A (aliquot TCGA-DD-AACS-01A-11D-A40R-10) from TCGA case TCGA-DD-AACS, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 39.6 years (14,473 days).
Specimen TCGA-DD-AACS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e85d65d2-4e86-408c-84cf-06bcda6a045b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AACS-10A (Blood Derived Normal), aliquot TCGA-DD-AACS-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e78669f5-3c04-4dae-a9a8-fb622f82eedd

The open-access MAF lists 57 somatic variants for this specimen: 45 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 43, Silent 12, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.376T>A p.Y126N | Missense Mutation (SNP) | VAF 46/50 reads (92%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs886039483, CM118879, COSV52661802, COSV52809424, COSV53031989, COSV53515469; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA3 | c.3242G>A p.R1081Q | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.017); catalogued as rs565777051, COSV57056697; called by muse, mutect2, varscan2
- ARID5B | c.3511C>G p.Q1171E | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.625); catalogued as COSV99690090; called by muse, mutect2, varscan2
- CBARP | c.419C>T p.T140M (on ENST00000382477; = p.T146M on NM_152769.3) | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as rs772563253, COSV53068727; called by muse, mutect2, varscan2
- CD81 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 54/110 reads (49%) | SIFT tolerated (0.83); PolyPhen benign (0.109); catalogued as rs538164293, COSV55134141; called by muse, mutect2, varscan2
- CUX2 | c.965G>A p.S322N | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1383148425, COSV55641666; called by muse, mutect2, varscan2
- DCAF4L1 | c.251A>T p.D84V | Missense Mutation (SNP) | VAF 73/161 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as COSV100295845; called by muse, mutect2, varscan2
- DUSP13 | c.295C>A p.P99T | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV100403609; called by muse, mutect2, varscan2
- EFCAB13 | c.2506C>G p.L836V | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.3); catalogued as COSV100516760; called by muse, mutect2
- EPHB3 | c.2663T>A p.I888N | Missense Mutation (SNP) | VAF 57/97 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100383185; called by muse, mutect2, varscan2
- FGF10 | c.261G>T p.K87N | Missense Mutation (SNP) | VAF 55/179 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.236); catalogued as COSV99240805; called by muse, mutect2, varscan2
- FRG2B | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 44/194 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV101423531; called by muse, mutect2
- GOLGB1 | c.2614G>A p.E872K | Missense Mutation (SNP) | VAF 59/101 reads (58%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.915); catalogued as COSV100511224; called by muse, mutect2, varscan2
- IPO7 | c.1844T>G p.I615S | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100797831; called by muse, mutect2, varscan2
- KCNH5 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 35/44 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100527372; called by muse, mutect2, varscan2
- KLF9 | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.054); catalogued as COSV101009602; called by muse, mutect2, varscan2
- LRRC4C | c.416T>C p.I139T | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99538964; called by muse, mutect2, varscan2
- MAGI3 | c.3095G>T p.G1032V | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100289779; called by muse, mutect2, varscan2
- MPRIP | c.1589G>A p.R530H | Missense Mutation (SNP) | VAF 65/110 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV57925524; called by muse, mutect2, varscan2
- MTRF1L | c.350T>G p.L117R | Missense Mutation (SNP) | VAF 65/165 reads (39%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.974); catalogued as COSV100922481; called by muse, mutect2, varscan2
- NBPF3 | c.718G>C p.E240Q | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.265); catalogued as COSV100558960; called by muse, mutect2
- NEIL2 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 37/46 reads (80%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs147360797; called by muse, mutect2, varscan2
- OR2M2 | c.222C>G p.I74M | Missense Mutation (SNP) | VAF 82/347 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.137); catalogued as COSV100677275; called by muse, mutect2, varscan2
- OR2W1 | c.763A>G p.I255V | Missense Mutation (SNP) | VAF 93/191 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV101013925; called by muse, mutect2, varscan2
- OR4N2 | c.515A>T p.N172I | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100269796; called by muse, mutect2, varscan2
- PFKFB2 | c.49A>G p.K17E | Missense Mutation (SNP) | VAF 37/155 reads (24%) | PolyPhen benign (0.017); catalogued as COSV100263176; called by muse, mutect2, varscan2
- PKHD1L1 | c.8255T>A p.V2752E | Missense Mutation (SNP) | VAF 72/255 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as COSV101006595; called by muse, mutect2, varscan2
- PRDM5 | c.1258C>G p.Q420E | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV99311009; called by muse, mutect2, varscan2
- PSMC6 | c.1153G>T p.V385F (on ENST00000612399; = p.V371F on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/98 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100648314; called by muse, mutect2, varscan2
- PTPRB | c.2182C>T p.R728W | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.189); catalogued as rs1179516030, COSV99718194; called by muse, mutect2, varscan2
- RBBP4 | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.069); catalogued as COSV100995350; called by muse, varscan2
- RBBP4 | c.1220A>T p.N407I | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV100995352; called by muse, varscan2
- RBL2 | c.1045G>C p.D349H | Missense Mutation (SNP) | VAF 61/67 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100043866; called by muse, mutect2, varscan2
- SCRN3 | c.1186G>T p.V396L | Missense Mutation (SNP) | VAF 197/398 reads (49%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV99767379; called by muse, mutect2, varscan2
- SIGLEC10 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs765309332, COSV100219251; called by muse, mutect2, varscan2
- SPSB2 | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs782809589, COSV99222958; called by muse, mutect2, varscan2
- SPTA1 | c.698C>G p.P233R | Missense Mutation (SNP) | VAF 59/119 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.21); catalogued as COSV100935242; called by muse, mutect2, varscan2
- SPTBN5 | c.9809G>A p.R3270Q | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.047); catalogued as rs548461931, COSV58017923; called by muse, mutect2, varscan2
- TECPR1 | c.1357A>G p.T453A | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV101130612; called by muse, mutect2, varscan2
- TECPR2 | c.3611A>G p.H1204R | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.952); catalogued as rs777143146, COSV100850124; called by muse, mutect2, varscan2
- TRIML1 | c.448A>G p.R150G | Missense Mutation (SNP) | VAF 60/64 reads (94%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs1043054135, COSV100206166; called by muse, mutect2, varscan2
- DNAH10 | c.6496A>T p.T2166S (on ENST00000409039; = p.T2105S on NM_207437.3) | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GEMIN2 | c.717_719del p.R240del | In Frame Del (DEL) | VAF 15/42 reads (36%) | called by pindel, varscan2
- GORAB | c.420-8_424delinsA p.X140_splice | Splice Site (DEL) | VAF 103/557 reads (18%) | called by pindel, varscan2*
- TRPV2 | c.718G>T p.A240S | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.772); called by muse, mutect2
- CRMP1 | c.537C>T p.S179= | Silent (SNP) | VAF 44/101 reads (44%) | catalogued as COSV100272121; called by muse, mutect2, varscan2
- DNA2 | c.1659C>T p.V553= | Silent (SNP) | VAF 128/329 reads (39%) | catalogued as rs1051825010, COSV100622691; called by muse, mutect2, varscan2
- EMC1 | c.186G>T p.V62= | Silent (SNP) | VAF 104/246 reads (42%) | catalogued as COSV100617500; called by muse, mutect2, varscan2
- FOXG1 | c.1227G>A p.L409= | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as COSV100486954; called by muse, mutect2, varscan2
- GNAT1 | c.897C>A p.I299= | Silent (SNP) | VAF 42/86 reads (49%) | catalogued as COSV99222454; called by muse, mutect2, varscan2
- LRRC7 | c.2655A>G p.R885= (on ENST00000651989 / NM_001370785.2; = p.R852= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 92/203 reads (45%) | catalogued as COSV99228275; called by muse, mutect2, varscan2
- RD3 | c.30C>T p.N10= | Silent (SNP) | VAF 40/149 reads (27%) | catalogued as rs774563819, COSV65362200, COSV65362702; called by muse, mutect2, varscan2
- RPH3A | c.270G>A p.V90= (on ENST00000389385 / NM_001143854.2; = p.V86= on NM_014954.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/93 reads (40%) | catalogued as COSV101231856; called by muse, mutect2, varscan2
- SEMA3G | c.1531C>A p.R511= | Silent (SNP) | VAF 51/129 reads (40%) | catalogued as COSV99202503; called by muse, mutect2, varscan2
- TENM4 | c.5412C>T p.I1804= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as rs893135364, COSV99574287; called by muse, mutect2, varscan2
- TMED9 | c.483G>A p.L161= | Silent (SNP) | VAF 91/206 reads (44%) | catalogued as COSV100215514; called by muse, mutect2, varscan2
- VWA3B | c.2460G>T p.L820= | Silent (SNP) | VAF 58/151 reads (38%) | catalogued as COSV101346095; called by muse, mutect2, varscan2
